Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A056, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A056-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

adenocarcinoma, endometrioid, NOS

8380/3

Site: Endometrium C54.1

hw
5/2/11

Specimens Submitted:

- 1: SP: Right external iliac lymph node (fs)
- 2: SP: Uterus, cervix, bilateral tubes and ovaries, bilateral parametria
- 3: SP: Portion of right parametrium
- 4: SP: Additional left parametrium
- 5: SP: Additional right parametrium
- 6: SP: Paracolpos, left
- 7: SP: Additional vaginal margin and right paracolpos
- 8: SP: Residual anterior vaginal tumor
- 9: SP: Left external iliac lymph nodes
- 10: SP: Left obturator node
- 11: SP: Left hypogastric lymph nodes
- 12: SP: Left common iliac lymph nodes
- 13: SP: Left para-aortic lymph nodes
- 14: SP: Right external iliac lymph nodes
- 15: SP: Right obturator lymph nodes
- 16: SP: Right hypogastric lymph nodes
- 17: SP: Right common iliac lymph nodes
- 18: SP: Right para-aortic lymph nodes

DIAGNOSIS:

- 1) LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- FOLLICULAR HYPERPLASIA.
- 2) UTERUS, CERVIX, BILATERAL TUBES AND OVARIES, BILATERAL PARAMETRIA; TOTAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS, FIGO GRADE III (> 50% SOLID GROWTH), NUCLEAR GRADE 3.
- THE TUMOR INVADERS TO > HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 2.4 CM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 2.5 CM.

** Continued on next page **

[page 2 of 3]
- THE UTERINE SEROSA IS NEGATIVE FOR CARCINOMA.
- ENDOCERVICAL INVASION IS PRESENT BOTH IN THE MUCOSA AND THE STROMA.
- VASCULAR INVASION IS PRESENT.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: LEIOMYOMA.
- THE RIGHT OVARY SHOWS ENDOMETRIOSIS.
- THE REMAINING ADNEXAL STRUCTURES ARE UNREMARKABLE.
- 3) PARAMETRIUM, RIGHT; EXCISION:
- BENIGN ADIPOSE TISSUE.
- 4) PARAMETRIUM, LEFT, ADDITIONAL; EXCISION:
- BENIGN FIBROVASCULAR TISSUE.
- 5) PARAMETRIUM, RIGHT ADDITIONAL EXCISION:
- BENIGN FIBROVASCULAR TISSUE.
- 6) PARACOLPOS; EXCISION:
- BENIGN FIBROCONNECTIVE TISSUE.
- 7) ADDITIONAL VAGINAL MARGIN AND RIGHT PARACOLPOS; EXCISION:
- ALMOST ENTIRELY DENUDED VAGINAL MUCOSA WITH SEVERE ACUTE AND CHRONIC
INFLAMMATION AND REACTIVE ATYPIA.
- NO TUMOR SEEN.
- 8) RESIDUAL ANTERIOR VAGINAL TUMOR; EXCISION:
- ALMOST ENTIRELY DENUDED VAGINAL MUCOSA WITH SEVERE ACUTE AND CHRONIC
INFLAMMATION AND REACTIVE ATYPIA.
- NO TUMOR SEEN.
- 9) LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 10) LYMPH NODE, LEFT OBTURATOR; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 11) LYMPH NODES, LEFT HYPOGASTRIC; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 12) LYMPH NODE, LEFT COMMON ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 13) LYMPH NODES, LEFT APARA-AORTIC; EXCISION:
- THIRTEEN BENIGN LYMPH NODES (0/13).
- 14) LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 15) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 16) LYMPH NODE, RIGHT HYPOGASTRIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 17) LYMPH NODES, RIGHT COMMON ILIAC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

** Continued on next page **

[page 3 of 3]
- 18) LYMPH NODES, RIGHT PARA-AORTIC; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).

NOTE: REPRESENTATIVE SECTIONS OF VAGINAL CUFF AND RIGHT EXTERNAL ILIAC LYMPH NODE WERE REVIEWED WITH DRS. [REDACTED]. THE CHANGES ARE INTERPRETED AS REACTIVE. DR. [REDACTED] NOTED THAT THE PATIENT HAS HAD VAGINAL PACKING, WHICH LIKELY CONTRIBUTED TO THE REACTIVE CHANGES NOTED.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file d0640aef-a3bb-41cf-b9db-a7cf4fd0914c (TCGA-AP-A056.008786AD-6CA8-488D-A5AC-BA558985E765.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).